TARGET case TARGET-00-NAAENF — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/ef4b5ddc-60f7-46f9-96dc-ab195a94076d

Biospecimens (1 sample)
- Sample TARGET-00-NAAENF-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.
